Surgical pathology report (de-identified scan), TCGA case TCGA-CQ-6219, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site University Health Network, Toronto, specimen TCGA-CQ-6219-01A (Primary Tumor).

[page 1 of 5]
Specimen(s) Received

1. Nck: RT LEVEL 1A
2. Nck: RT LEVEL 1B
3. Nck: RT LEVEL 2A
4. Nck: RT LEVEL 2B
5. Nck: RT LEVEL 3
6. Nck: RT LEVEL 4
7. Lymph node: Right submental node/ [REDACTED]
8. Neck: Right glossectomy- suture anterior margin / [REDACTED]
9. Oral Cavity; Right deep tonsil margin / [REDACTED]
10. Oral Cavity: Posterior tongue base/ [REDACTED]
11. Oral Cavity: Anterior tongue base/ [REDACTED]
12. Neck: Anterior Deep margin/ [REDACTED]
13. Neck: Posterior deep margin/ [REDACTED]
14. Lymph node: Left level II node / [REDACTED]
15. Lymph node: Left level III node / [REDACTED]
16. Neck: Left neck level I,II ,III [REDACTED]
17. Neck: Revision right parapharyngeal space/ [REDACTED]
18. Neck: Revision glossectomy- long stitch anterior portion ,short suture medial aspect / [REDACTED]

Diagnosis

1. Right neck level IA.
Three lymph nodes negative for tumor (0/3).
2. Right neck level IB.
Six lymph nodes negative for tumor (0/6).
Submandibular gland with chronic inflammation.
3. Right neck level IIA.
Metastatic squamous cell carcinoma involving one of nine lymph nodes (1/9).
- a. Largest involved lymph node measures 3.5 cm.
- b. Extracapsular invasion present.
4. Right neck level IIB.

[page 2 of 5]
Five lymph nodes negative for tumor (0/5).

5. Right neck level III.

Twelve lymph nodes negative for tumor (0/12).

6. Right neck level IV.

Ten lymph nodes negative for tumor (0/10).

7. Right submental lymph node.

One lymph node negative for tumor (0/1).

8. Oral cavity; tongue; right glossectomy.

Squamous cell carcinoma, moderately differentiated.

a. Tumor maximum diameter 5.5 cm.

b. Tumor thickness 3.6 cm.

c. Perineural invasion present.

d. No lymphatic/vascular invasion.

e. The medial and lateral pharyngeal margins are positive for tumor. Remaining margins are negative for tumor.

9. Right deep tonsil margin.

Negative for tumor.

10. Posterior tongue base.

Negative for tumor.

11. Anterior tongue base.

Negative for tumor.

12. Anterior deep margin.

Negative for tumor.

13. Posterior deep margin.

Negative for tumor.

14. Left level II lymph node.

One lymph node negative for tumor (0/1).

15. Left level III lymph node.

One lymph node negative for tumor (0/1).

16. Left neck level I-III.

Six lymph nodes negative for tumor (0/6).

17. Revision right parapharyngeal space.

Negative for tumor.

18. Revision glossectomy.

Negative for tumor.

Synoptic Data

Specimen Type:

Resection:right glossectomy.

Tumor Site:

Tongue

Histologic Type:

Squamous cell carcinoma, conventional

[page 3 of 5]
Tumor Size:	Greatest dimension: 5.5 cm
	Tumor thickness: 3.6 cm
Histologic Grade:	G2: Moderately differentiated
Venous/Lymphatic (Large/Small Vessel) Invasion (V/L):	Absent
Perineural Invasion:	Present
Margins:	Margins uninvolved by tumor
Pathologic Staging (pTNM):	pT3: Tumor or lip or oral cavity more than 4 cm in greatest dimension
	pN2a: Metastasis in a single ipsilateral lymph node, more than 3 cm but not more than 6 cm in greatest dimension for all aerodigestive sites except nasopharynx
	Number of regional lymph nodes examined: 55
	Number of regional lymph nodes involved: 1
	Extra-capsular extension of nodal tumor: Present
	pMX: Distant metastasis cannot be assessed

verified by:

Electronically

Clinical History

ORAL CA

Gross Description

1. The specimen is labeled with the patient's name and "right level 1A". It consists of portion of fibroadipose tissue measuring 4.5 x 2 x 1 cm. Multiple lymph nodes ranging from 0.1 x 0.1 x 0.1 to 0.5 x 0.4 x 0.4 cm are identified.

1A multiple lymph nodes

2. The specimen is labeled with the patient's name and "right level 1B". It consists of portion of fibroadipose tissue measuring 4.5 x 4.5 x 2.8cm. The submandibular gland measures 3.5 x 2.5 x 2 cm. Multiple lymph nodes ranging from 0.3 x 0.3 x 0.3 to 1.2 x 1 x 1.0 cm are identified.

2A submandibular gland

2B two lymph nodes

2C one lymph node

2D one lymph node

2E one lymph node

2F one lymph node

3. The specimen is labeled with the patient's name and "right level 2A". It consists of portion of fibroadipose tissue measuring 5 x 3.5 x 1.4 cm. Multiple lymph nodes ranging from 0.3 x 0.3 x 0.2 to 3.5 x 1.6 x 1.0 cm are identified. One lymph node is friable and is involved by tumor. Representative sections are submitted.

3A multiple lymph nodes

3B-3D largest lymph node

3E-3H involved lymph node with cluster of smaller lymph nodes

4. The specimen is labeled with the patient's name and "right level 2B". It consists of portion of fibroadipose tissue measuring 2 x 1.5 x 1.2 cm. Multiple lymph nodes ranging from 0.2 x 0.2 x 0.2 to 0.5 x 0.5 x 0.4 cm are identified. The specimen is submitted in toto.

4A-4C lymph nodes cluster

[page 4 of 5]
5. The specimen is labeled with the patient's name and "right level 3". It consists of portion of fibroadipose tissue measuring 8 x 4 x 3 cm. Multiple lymph nodes ranging from 0.2 x 0.2 x 0.2 to 1.6 x 0.5 x 0.8 cm are identified.

- 5A one lymph node
- 5B one lymph node
- 5C one lymph node
- 5D multiple lymph nodes
- 5E multiple lymph nodes
- 5F two lymph nodes
- 2G cluster of lymph nodes

6. The specimen is labeled with the patient's name and "right level 4". It consists of portion of fibroadipose tissue measuring 3.5 x 2.5 x 1.8 cm. Multiple lymph nodes ranging from 0.2 x 0.2 x 0.2 to 1.5 x 0.6 x 0.4 cm are identified. Representative sections are submitted.

- 6A-6B multiple lymph nodes
- 6C one lymph node

7. The specimen is labeled with the patient's name and "right submental node". It consists of one lymph node measuring 0.5 x 0.4 x 0.4 cm.

- 7A one lymph node

8. The specimen is labeled the patient's name and "right glossectomy suture anterior margin". It consists of an oriented portion of right tongue measuring 3.5 SI x 4.0 ML x 7.8 AP cm. There is a partly ulcerated tumor involving the lateral surface. The tumor measures 3.6 cm SI x 3.5 cm ML x 5.5 cm AP. The tumor is located at 0.1 cm from the lateral margin, 0.1 cm from the medial margin, 1.0 cm from the inferior deep margin, 0.8 cm from the anterior margin, and 0.3 from the posterior margin. Representative sections are submitted.

- 8A lateral pharyngeal margin, frozen section control
- 8B posterior margin
- 8C anterior margin
- 8D medial margin
- 8E inferior deep margin
- 8F-8H tumor

9. The specimen is labeled with the patient's name and "right deep tonsil margin". It consists of a fragment of tissue measuring 0.4 x 0.3 x 0.2 cm. The specimen is submitted in toto for frozen section. The specimen is kept frozen as per research protocol.

- 9A frozen section slide

10. The specimen is labeled with the patient's name and "posterior tongue base". It consists of a fragment of tissue measuring 1.3 x 0.3 x 0.2 cm. The specimen is submitted in toto for frozen section. The specimen is kept frozen as per research protocol.

- 10A frozen section slide

11. The specimen is labeled with the patient's name and "anterior tongue base". It consists of a fragment of tissue measuring 1 x 0.3 x 0.3 cm. The specimen is submitted in toto for frozen section. The specimen is kept frozen as per research protocol.

- 11A frozen section slide

12. The specimen is labeled with the patient's name and "anterior deep margin". It consists of a fragment of tissue measuring 0.6 x 0.3 x 0.2 cm. The specimen is submitted in toto for frozen section. The specimen is kept frozen as per research protocol.

- 12A frozen section slide

[page 5 of 5]
13. The specimen is labeled with the patient's name and "posterior deep margin". It consists of a fragment of tissue measuring 0.5 x 0.3 x 0.2 cm. The specimen is submitted in toto for frozen section. The specimen is kept frozen as per research protocol.

13A frozen section slide

14. The specimen is labeled with the patient's name and "left level 2 node". It consists of a fragment of tissue measuring 1.2 x 0.7 x 0.2 cm. The specimen is submitted in toto for frozen section. The specimen is kept frozen as per research protocol.

14A frozen section slide

15. The specimen is labeled with the patient's name and as "left level 3 node". It consists of a fragment of tissue measuring 1 x 0.6 x 0.3 cm. The specimen is submitted in toto for frozen section.

15A frozen section control

16. The specimen is labeled with the patient's name and "left neck level 1, 2 and 3 ". It consists of portion of fibroadipose tissue measuring 5.5 x 4 x 2.2 cm. The submandibular gland measures 3.5 x 1.8 x 2.6 cm and is unremarkable. Multiple lymph nodes ranging from 0.8 x 0.5 x 0.5 to 2 x 1.2 x 0.4 cm are identified. Representative sections are submitted.

16A submandibular gland

16B one lymph node

16C one lymph node

16D one lymph node

16E one lymph node

16F one lymph node

16G one lymph node

17. The specimen is labeled with the patient's name and "revision right parapharyngeal space". It consists of a portion of muscle with mucosa. No lesion is identified.

17A-17C specimen in toto

18. The specimen is labeled with the patient's name and "revision glossectomy-long stitch anterior portion short suture medial aspect". It consists of an oriented piece of tongue measuring 2.7 SI x 0.8 ML x 2.5 AP cm. No lesion is identified. It is painted with silver nitrate and the medial face over coated with India ink. The superior edge over coated with green ink. The specimen is serially sectioned from anterior to posterior and submitted in toto sequentially.

18A anterior margin

18B-18D midsections

18E posterior margin

Quick Section Diagnosis

8. Right glossectomy:

8A) Lateral (parapharyngeal) margin: Positive for squamous cell carcinoma

9A) Right deep tonsil margin: Negative for carcinoma

10a) Posterior tongue base: Negative for carcinoma

11A) Anterior tongue base: Negative for carcinoma

12A) Anterior deep margin: Negative for carcinoma

13A) Posterior deep margin: Negative for carcinoma

14A) Left level II lymph node: Negative for carcinoma

15A) Left level III lymph node: Negative for carcinoma

Reported to Dr. [REDACTED] at [REDACTED]

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file 142bc2bb-da40-4b4a-866f-bed949e41dbe (TCGA-CQ-6219.D0224177-93FC-486A-984C-3F9043276FBF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).